Gene-level copy-number profile of specimen HCM-BROD-0703-C16-85M from HCMI case HCM-BROD-0703-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.3 years (19,452 days).
Specimen HCM-BROD-0703-C16-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 94cd58cd-ef0b-4283-bc10-38bf44d130ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0703-C16-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,256 have no estimate.
https://portal.gdc.cancer.gov/files/75b87a85-4efa-43a2-91bb-0458bc9d8004

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 4,161; copy number 2: 16,131; copy number 3: 29,881; copy number 4: 7,672; copy number 5: 398; copy number 6: 94; copy number 7: 11; copy number 126: 14; copy number 134: 1; copy number 135: 3.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:33,578,219–33,751,195, 1 gene: ASXL3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 29 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,549,940–32,560,022, 2 genes, copy number 7 (within-gene range 4–7): RNU1-61P, HLA-DRB6.
- chr10:52,765,380–53,030,024, 3 genes, copy number 135: MBL2, Y_RNA, LINC02672.
- chr10:53,766,400–53,766,614, 1 gene, copy number 134: AL365496.1.
- chr10:120,608,580–121,739,730, 14 genes, copy number 126: AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1.
- chr14:37,556,158–38,194,281, 9 genes, copy number 7 (within-gene range 6–7): AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2.

Autosomal genes at a single copy (total copy number 1): 1,817. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
